Somatic mutation profile of tumor specimen TCGA-JY-A938-01A (aliquot TCGA-JY-A938-01A-11D-A37C-09) from TCGA case TCGA-JY-A938, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 75.7 years (27,633 days).
Specimen TCGA-JY-A938-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2d26bd7-5ab4-4309-a1be-8468207deac7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JY-A938-10A (Blood Derived Normal), aliquot TCGA-JY-A938-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30a4518f-723c-4f00-9b6e-08d9cb8448db

The open-access MAF lists 149 somatic variants for this specimen: 111 protein-altering or splice-affecting, 35 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 35, Frame Shift Del 8, In Frame Del 3, Nonsense Mutation 3, 3'Flank 2, 5'UTR 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 22/51 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 11/42 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADRA2C | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57467182; called by muse, mutect2, varscan2
- ANKRD12 | c.5938C>T p.R1980C | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1298887548; called by muse, mutect2, varscan2
- ANKRD17 | c.7652C>T p.A2551V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs766396062; called by muse, mutect2, varscan2
- ANO8 | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1314585686; called by muse, mutect2, varscan2
- ARHGAP39 | c.1595del p.S532Tfs*5 | Frame Shift Del (DEL) | VAF 9/69 reads (13%) | catalogued as COSV99431578; called by mutect2, pindel, varscan2
- CDH7 | c.2317G>A p.A773T | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59881252; called by muse, mutect2, varscan2
- CHPF | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs867222250; called by muse, mutect2, varscan2
- COL6A6 | c.5626G>A p.A1876T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs1284687222, COSV100650756; called by muse, mutect2, varscan2
- CRX | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as rs376982187; called by muse, mutect2, varscan2
- DSCAM | c.5129C>T p.S1710L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.619); catalogued as rs776525485, COSV68037161; called by muse, mutect2, varscan2
- DSCAML1 | c.2219G>A p.R740Q (on ENST00000321322; = p.R680Q on NM_020693.4) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.723); catalogued as rs1430840890, COSV58381799; called by muse, mutect2, varscan2
- FAM187B | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.36); catalogued as rs762057149, COSV100220098; called by muse, mutect2, varscan2
- FGF4 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.074); catalogued as rs1174143141, COSV51450387; called by muse, mutect2
- FMN2 | c.3013G>A p.G1005R | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.971); catalogued as rs534635159, COSV100147174, COSV60430473; called by muse, varscan2
- FMO4 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs142319717; called by muse, mutect2, varscan2
- FRMD6 | c.1396G>A p.E466K (on ENST00000344768 / NM_001267046.2; = p.E458K on NM_152330.4) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.444); catalogued as COSV100655706; called by muse, mutect2, varscan2
- FSTL1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs554312023, COSV99820760; called by muse, mutect2, varscan2
- IGLV2-33 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.021); catalogued as rs1465398825; called by muse, mutect2, varscan2
- IGSF3 | c.3370G>A p.A1124T (on ENST00000369486 / NM_001007237.3; = p.A1144T on NM_001542.4) | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as rs368581214; called by muse, mutect2, varscan2
- LARS1 | c.3505G>A p.D1169N (on ENST00000394434 / NM_020117.11; = p.D1142N on NM_016460.3) | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs753633864, COSV104388553; called by muse, mutect2, varscan2
- LCT | c.3817G>A p.E1273K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs751898984, COSV51548234; called by muse, mutect2, varscan2
- LRIT1 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as rs1380894095; called by muse, mutect2, varscan2
- LRIT2 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs201652904, COSV100259024; called by muse, mutect2, varscan2
- LYSMD3 | c.273_274del p.R91Sfs*2 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | catalogued as rs746927746; called by pindel, varscan2
- METTL9 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.521); catalogued as rs771501450; called by muse, mutect2, varscan2
- MYOM3 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.734); catalogued as rs760566144; called by muse, mutect2, varscan2
- OR2G2 | c.724G>T p.G242W | Missense Mutation (SNP) | VAF 60/239 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60739578; called by muse, mutect2, varscan2
- OR51F1 | c.467T>C p.L156P | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV58579646; called by muse, mutect2, varscan2
- OR5D18 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376041728, COSV100450973; called by muse, mutect2, varscan2
- PLEC | c.10124C>T p.P3375L (on ENST00000322810 / NM_201380.4; = p.P3265L on NM_000445.5) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs782085661; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- PON3 | c.818A>T p.D273V | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs778295748; called by muse, mutect2, varscan2
- PRKAA2 | c.1616T>G p.F539C | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64803626; called by muse, mutect2, varscan2
- RPA1 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs139432886; called by muse, mutect2, varscan2
- SFRP4 | c.431C>T p.T144M | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1257326476; called by muse, mutect2, varscan2
- SIPA1L1 | c.2288C>T p.S763F | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV62170856; called by muse, mutect2, varscan2
- SLC6A11 | c.314T>C p.F105S | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV54390607; called by muse, mutect2, varscan2
- SPTBN4 | c.5347C>T p.R1783W | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs759964383, COSV58948161; called by muse, mutect2
- SUPT5H | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs570927495, COSV63241257; called by muse, mutect2, varscan2
- TONSL | c.1486_1488del p.D496del | In Frame Del (DEL) | VAF 16/110 reads (15%) | catalogued as rs778043482; called by pindel, varscan2
- VCAN | c.2911C>A p.H971N | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.272); catalogued as COSV54117395; called by muse, mutect2, varscan2
- VRTN | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs376151213; called by muse, mutect2, varscan2
- YY1AP1 | c.295_296insTC p.A99Vfs*20 (on ENST00000295566 / NM_139118.2; = p.A22Vfs*20 on NM_018253.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 20/112 reads (18%) | catalogued as rs1215499139; called by muse*, mutect2, varscan2*
- YY1AP1 | c.293_294del p.Q98Rfs*2 (on ENST00000295566 / NM_139118.2; = p.Q21Rfs*2 on NM_018253.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/117 reads (19%) | catalogued as rs1240584329; called by muse*, mutect2, varscan2*
- ZNF221 | c.1306C>T p.R436* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as rs148293806; called by muse, mutect2, varscan2
- ZNF347 | c.1576T>C p.S526P | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV61967871; called by muse, mutect2, varscan2
- ZNF804A | c.1884A>T p.E628D | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56445379; called by muse, mutect2, varscan2
- ZZEF1 | c.8725C>T p.R2909C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as rs867775380, COSV101067697; called by muse, mutect2, varscan2
- ADGRB3 | c.1965A>C p.E655D | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- AMD1 | c.149C>G p.S50* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- ARHGAP30 | c.941-1G>A p.X314_splice | Splice Site (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- ATM | c.8302G>C p.E2768Q | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.706); called by muse, mutect2
- C1R | c.1029G>C p.Q343H (on ENST00000536053 / NM_001354346.2; = p.Q329H on NM_001733.7) | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.058); called by muse, mutect2
- C1orf105 | c.240A>C p.Q80H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- C1orf198 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- CCDC178 | c.2042A>T p.E681V (on ENST00000383096 / NM_001105528.3; = p.E643V on NM_198995.3) | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- CEP170 | c.4505C>A p.A1502D | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CEP350 | c.2462A>G p.K821R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- COL5A2 | c.1760T>G p.L587R | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- CRACD | c.107T>G p.V36G | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CTNND1 | c.922del p.T308Lfs*17 | Frame Shift Del (DEL) | VAF 11/66 reads (17%) | called by mutect2, pindel, varscan2
- CYP21A2 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CYTH4 | c.472_484del p.Q158Gfs*2 | Frame Shift Del (DEL) | VAF 20/115 reads (17%) | called by mutect2, pindel, varscan2
- DCUN1D5 | c.347A>C p.D116A | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- DHRS3 | c.355A>G p.I119V | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- DNMBP | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DOCK3 | c.379A>G p.R127G | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- DPF3 | c.506A>C p.K169T | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ENTPD6 | c.856A>G p.T286A | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- ERBB4 | c.1290T>G p.S430R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- EVC2 | c.2669T>C p.V890A | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXO45 | c.474A>C p.E158D | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- FGFBP1 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- FMN2 | c.2233del p.Q745Rfs*11 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- FRS2 | c.624C>A p.N208K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.005); called by muse, mutect2
- GALNT14 | c.1550G>T p.C517F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GIGYF2 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GPR26 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2
- GRM5 | c.3265G>A p.V1089I (on ENST00000305447 / NM_001143831.2; = p.V1057I on NM_000842.4) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- H2BC12 | c.206A>G p.D69G | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- HAO2 | c.951A>C p.E317D | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- INF2 | c.2675A>C p.E892A | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- KCNH8 | c.1279T>G p.F427V | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KRTAP10-7 | c.109T>A p.C37S | Missense Mutation (SNP) | VAF 54/283 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LRRC71 | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MOG | c.736C>A p.P246T | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MRPS14 | c.312G>T p.W104C | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- NBEA | c.4610T>C p.L1537P | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- OR2T4 | c.130T>G p.F44V | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PBRM1 | c.2615_2626del p.F872_R876delinsC | In Frame Del (DEL) | VAF 13/76 reads (17%) | called by mutect2, pindel*, varscan2*
- PCDH15 | c.3677A>T p.D1226V | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PGM1 | c.934G>A p.V312I | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PLEKHG4B | c.1523C>A p.A508D (on ENST00000283426; = p.A864D on NM_052909.5) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PPP1R3A | c.1651A>C p.S551R | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- PPP6R1 | c.1430del p.N477Tfs*15 | Frame Shift Del (DEL) | VAF 22/87 reads (25%) | called by mutect2, pindel, varscan2
- PXDN | c.718G>C p.E240Q | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); called by muse, mutect2
- RGS4 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- SAMSN1 | c.712A>G p.S238G | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SEC23A | c.786_792del p.S263Gfs*6 | Frame Shift Del (DEL) | VAF 12/78 reads (15%) | called by mutect2, pindel*, varscan2
- SERPINA12 | c.358A>T p.I120F | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SLC4A7 | c.3004T>G p.F1002V | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNCAIP | c.2634_2639del p.N879_N880del | In Frame Del (DEL) | VAF 5/17 reads (29%) | called by mutect2, varscan2
- SPTA1 | c.250C>A p.P84T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- SVEP1 | c.8972C>A p.S2991Y | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); called by muse, mutect2
- SYT3 | c.346C>A p.H116N | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- TRIM16L | c.7T>A p.F3I | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRIM49 | c.493A>C p.T165P | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF483 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ZNF768 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF776 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 41/184 reads (22%) | called by muse, mutect2, varscan2
- ANKRD12 | c.6114C>A p.I2038= | Silent (SNP) | VAF 18/110 reads (16%) | called by muse, mutect2, varscan2
- BCL9L | c.2202G>A p.A734= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs1176871909, COSV52689107; called by muse, mutect2, varscan2
- C12orf56 | c.432C>T p.N144= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as rs370367135; called by muse, mutect2, varscan2
- C1QTNF6 | c.729C>T p.R243= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs767660674; called by muse, varscan2
- C1orf115 | c.141G>A p.A47= | Silent (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2
- CCAR2 | c.1701C>T p.V567= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs1428560693, COSV99373947; called by muse, mutect2, varscan2
- CLGN | c.978T>C p.N326= | Silent (SNP) | VAF 23/107 reads (21%) | called by muse, mutect2, varscan2
- CUL4A | c.1314C>A p.I438= (on ENST00000375440 / NM_001008895.4; = p.I338= on NM_003589.3) | Silent (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- DOHH | c.348C>T p.I116= | Silent (SNP) | VAF 18/117 reads (15%) | called by muse, mutect2, varscan2
- FAM47A | c.1653T>C p.R551= | Silent (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- FUCA1 | c.1236C>T p.S412= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs1310643655; called by muse, mutect2, varscan2
- IMPG2 | c.2685T>G p.T895= | Silent (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- KAT5 | c.489G>A p.E163= | Silent (SNP) | VAF 27/107 reads (25%) | called by muse, mutect2, varscan2
- MATN4 | c.180C>T p.L60= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as rs1377164662; called by muse, mutect2
- MED24 | c.699G>A p.A233= | Silent (SNP) | VAF 39/82 reads (48%) | catalogued as rs769426925, COSV100673144; called by muse, mutect2, varscan2
- MROH8 | c.1464C>T p.A488= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs746001637, COSV99458273; called by muse, mutect2, varscan2
- MRPL4 | c.409C>A p.R137= | Silent (SNP) | VAF 23/77 reads (30%) | called by muse, mutect2, varscan2
- NAAA | c.648C>T p.V216= | Silent (SNP) | VAF 23/74 reads (31%) | called by muse, mutect2, varscan2
- NALCN | c.4689A>T p.I1563= | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- NCCRP1 | c.675C>A p.G225= | Silent (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2, varscan2
- NOTCH3 | c.1689C>T p.I563= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs781266677, COSV54625674; called by muse, mutect2, varscan2
- NPTXR | c.1413C>T p.N471= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as rs1336098615; called by muse, mutect2
- NRXN1 | c.2328G>A p.V776= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV100454883; called by muse, mutect2, varscan2
- OR4C12 | c.711C>A p.T237= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as COSV58859803; called by muse, mutect2
- PCDHGC5 | c.1455T>C p.D485= | Silent (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- PPIB | c.117G>C p.G39= | Silent (SNP) | VAF 43/156 reads (28%) | called by muse, mutect2, varscan2
- PTCD1 | c.1296G>A p.K432= | Silent (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- RAB32 | c.414T>G p.A138= | Silent (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
- SIGLEC11 | c.1311C>T p.H437= | Silent (SNP) | VAF 27/184 reads (15%) | catalogued as rs374158248; called by muse, varscan2
- SLC2A14 | c.1506C>T p.D502= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs143806494; called by muse, mutect2, varscan2
- SLC7A9 | c.429C>A p.G143= | Silent (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- SP8 | c.1284C>T p.S428= (on ENST00000361443 / NM_198956.4; = p.S446= on NM_182700.6) | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV63866125; called by muse, mutect2, varscan2
- TNS3 | c.3171G>A p.A1057= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs200823221, COSV60799163; called by muse, mutect2, varscan2
- XPNPEP2 | c.1116C>T p.D372= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs759885261; called by muse, mutect2, varscan2
- ZFX | c.1734C>T p.C578= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV58449042; called by muse, mutect2, varscan2
- COMMD9 | chr11:36271521 G>A | 3'Flank (SNP) | VAF 11/36 reads (31%) | catalogued as rs1373506763; called by muse, mutect2, varscan2
- SPATA1 | c.-2A>C | 5'UTR (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- ST8SIA2 | chr15:92472289 G>A | 3'Flank (SNP) | VAF 13/56 reads (23%) | catalogued as rs751058990; called by muse, mutect2, varscan2
